CGCI case HTMCP-02-06-01158 — HIV+ Tumor Molecular Characterization Project - Lung Cancer (CGCI-HTMCP-LC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9699cb6d-90e8-4c13-b659-82259976feec

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 67 years; Vital status: Dead; Days to death: 122 days.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Classification of tumor: primary; Age at diagnosis: 67.8 years (24,771 days); Year of diagnosis: 2015; Method of diagnosis: Biopsy; AJCC staging edition: 7th; AJCC clinical T: T3; AJCC clinical N: NX; AJCC clinical M: MX; AJCC clinical stage: Stage IIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 122 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Initial disease status: Initial Diagnosis; Days to treatment start: 21 days; Days to treatment end: 21 days; Number of cycles: 1.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 0 days; Karnofsky performance status: 90; ECOG performance status: 1.
- Disease response: With Tumor.
- Follow-up contact recording only the day: day 122.

Molecular and laboratory tests
- NKX2-1 (IHC): Positive.
- Test (IHC): Negative; Specialized molecular test: P40.

Other clinical attributes
- Day 0: Weight: 66.6 kg; Height: 167.5 cm; BMI: 23.7.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples)
- Sample HTMCP-02-06-01158-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-02-06-01158-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-02-06-01158-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Adenocarcinoma, Not Otherwise Specified; Tumor status: With tumor; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Lost to follow-up: No; Tobacco smoking history indicator: 1; New tumor event diagnosis indicator: No.
- Anatomic neoplasm subdivision list: Anatomic organ subdivision: Upper lobe.
- Primary pathology: Lymph nodes examined: No; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: Tru-cut biopsy.
- Treatments, Treatment: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Carboplatin + Paclitaxel; Pharma adjuvant cycles count: 1.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-LC_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-02-06-01158-01B-01D-10409:
- % tumour top: 60
- % tumour bottom: 60

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-LC_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-02-06-01158-01B-01R-10409:
- % tumour top: 60
- % tumour bottom: 60
